FM case AD9669 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/29c8175b-2a32-45cf-81ff-2518c202285d

Male, 59.0 years: diagnosis not reported by GDC; metastasis biopsied or resected from the pelvis. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
